Somatic mutation profile of tumor specimen TCGA-23-1022-01A (aliquot TCGA-23-1022-01A-02W-0486-08) from TCGA case TCGA-23-1022, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.9 years (24,798 days).
Specimen TCGA-23-1022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e58227c-01af-45ea-a884-103b280e59e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1022-10A (Blood Derived Normal), aliquot TCGA-23-1022-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/668aa041-2cb7-4226-b981-5de16fcf5d3a

The open-access MAF lists 226 somatic variants for this specimen: 179 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 44, Frame Shift Del 7, Nonsense Mutation 6, Frame Shift Ins 4, In Frame Del 2, RNA 2, Splice Site 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3359G>A p.G1120E | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as rs28933379, COSV57359343, COSV57363821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HEXA | c.1305C>T p.Y435= | Silent (SNP) | VAF 508/692 reads (73%) | catalogued as rs587779406, CS102998, COSV51507879; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 234/256 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs879254249, COSV52676020, COSV52700231, COSV52728094, COSV52766542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC10 | c.1060C>T p.Q354* (on ENST00000372530 / NM_001198934.2; = p.Q311* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/113 reads (31%) | catalogued as COSV55087429, COSV55092062; called by muse, mutect2, varscan2
- ABRA | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV61733178, COSV61733580; called by muse, mutect2, varscan2
- ACAA2 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53270773, COSV53271749; called by muse, mutect2, varscan2
- ACOT9 | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV60538564; called by muse, mutect2, varscan2
- ACSM4 | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 208/532 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV68068822; called by muse, mutect2, varscan2
- ADCY3 | c.2190C>A p.Y730* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV53170751; called by muse, mutect2, varscan2
- ADGRD1 | c.107T>A p.F36Y | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV55452429; called by muse, mutect2, varscan2
- ADGRG7 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs765888895, COSV56293266; called by muse, mutect2, varscan2
- ADGRL3 | c.985T>A p.S329T (on ENST00000506720 / NM_001322402.2; = p.S261T on NM_015236.6) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.138); catalogued as rs972384097, COSV72270421; called by muse, mutect2, varscan2
- ADORA2B | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs762496834, COSV58482853, COSV58483601; called by muse, mutect2, varscan2
- AIFM3 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100104055; called by muse, mutect2, varscan2
- AKAP6 | c.6536C>G p.S2179C | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.237); catalogued as COSV104384199, COSV55225758; called by muse, mutect2
- ALPK3 | c.2872G>C p.D958H | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51937408; called by muse, mutect2, varscan2
- AOC1 | c.1979T>C p.I660T | Missense Mutation (SNP) | VAF 119/582 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs781356994, COSV62870139; called by muse, mutect2, varscan2
- APC | c.6014C>G p.S2005* | Nonsense Mutation (SNP) | VAF 61/129 reads (47%) | catalogued as COSV57366916; called by muse, mutect2, varscan2
- ARHGAP30 | c.2329C>G p.Q777E | Missense Mutation (SNP) | VAF 215/1059 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs770292771, COSV63518275; called by muse, mutect2, varscan2
- ASNSD1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV53624471; called by muse, mutect2
- B9D2 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 38/161 reads (24%) | catalogued as COSV54684592; called by muse, mutect2, varscan2
- BCL9L | c.3380dup p.P1128Tfs*42 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | catalogued as rs751794665; called by mutect2, varscan2
- BMPER | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 129/565 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.152); catalogued as COSV51827211; called by muse, mutect2, varscan2
- BOLA1 | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.157); catalogued as COSV64967444; called by muse, mutect2, varscan2
- C12orf29 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 18/596 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100467473; called by muse, mutect2
- C1QTNF1 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV59263311; called by muse, mutect2, varscan2
- C1orf174 | c.598G>T p.G200* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | catalogued as COSV100851680; called by muse, mutect2
- C2CD3 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 73/621 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58090296, COSV58097566; called by muse, mutect2, varscan2
- C2CD5 | c.2455G>C p.D819H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV61726535; called by muse, mutect2, varscan2
- CAPS2 | c.1584A>C p.K528N | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV60827717; called by muse, mutect2, varscan2
- CELF1 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60114278; called by muse, mutect2, varscan2
- CHRM2 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 148/887 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV57779984; called by muse, mutect2, varscan2
- CHST10 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 44/834 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.255); catalogued as COSV99958571, COSV99958602; called by muse, mutect2
- CHST9 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 137/537 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52445240; called by muse, mutect2, varscan2
- COL11A2 | c.755C>A p.P252Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.941); catalogued as COSV59500480; called by muse, mutect2, varscan2
- COL16A1 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV54711289; called by muse, mutect2, varscan2
- COL1A2 | c.2809G>A p.G937S | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM070783, COSV51961112, COSV51963189; called by muse, mutect2, varscan2
- COL9A1 | c.28T>A p.F10I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.009); catalogued as COSV61835809; called by muse, mutect2, varscan2
- COPB2 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 108/531 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs560518160, COSV60350829; called by muse, mutect2, varscan2
- CPSF1 | c.3404G>A p.C1135Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV100450097; called by muse, mutect2
- CSRP2 | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV60703182; called by muse, mutect2, varscan2
- CUL5 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as COSV67609772; called by muse, mutect2, varscan2
- CYP4F12 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV61175543; called by muse, mutect2, varscan2
- DEFB114 | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV59038345; called by muse, mutect2, varscan2
- DENND2A | c.928T>G p.S310A | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV52056161; called by muse, mutect2, varscan2
- DLG2 | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 34/936 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV99711742; called by muse, mutect2
- DOC2A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1487993007, COSV58752258; called by muse, mutect2, varscan2
- ENC1 | c.1039G>C p.G347R | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56628604, COSV56630588; called by muse, mutect2, varscan2
- ENPP1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1370913047, COSV62934810; called by muse, mutect2, varscan2
- ESR1 | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV52793878, COSV99237102; called by muse, mutect2
- FAM120B | c.2713_2714insT p.D905Vfs*102 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | catalogued as COSV53006876; called by mutect2, pindel, varscan2
- FAM135B | c.4175T>C p.F1392S | Missense Mutation (SNP) | VAF 95/634 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52713244; called by muse, mutect2, varscan2
- FAM187B | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61201578; called by muse, mutect2, varscan2
- FAT3 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.52); catalogued as rs765974517, COSV53152547; called by muse, mutect2, varscan2
- FBXO24 | c.279G>C p.Q93H (on ENST00000241071 / NM_033506.3; = p.Q131H on NM_012172.5) | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV53828416; called by muse, mutect2, varscan2
- FOCAD | c.2374G>T p.G792W | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58105081; called by muse, mutect2, varscan2
- FOXO4 | c.574dup p.R192Pfs*9 | Frame Shift Ins (INS) | VAF 5/53 reads (9%) | catalogued as rs1405991935; called by mutect2, pindel
- FREM2 | c.5888T>C p.I1963T | Missense Mutation (SNP) | VAF 130/205 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs753924671, COSV54846299; called by muse, mutect2, varscan2
- FSIP1 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs997415836, COSV63226195; called by muse, mutect2, varscan2
- GFRA3 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV99218236; called by muse, mutect2
- GJA8 | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53789935; called by mutect2, varscan2
- GLIS3 | c.947C>G p.P316R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV100173017; called by muse, mutect2, varscan2
- GM2A | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV100852020; called by muse, mutect2
- GPR55 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV67408281; called by muse, mutect2, varscan2
- HCN4 | c.962A>T p.E321V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56086026; called by muse, mutect2, varscan2
- HEATR5A | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 100/389 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV66343974; called by muse, mutect2, varscan2
- HECTD4 | c.11771G>A p.C3924Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV66396846; called by muse, mutect2, varscan2
- HECW2 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 114/724 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV53669140; called by muse, mutect2, varscan2
- HEXB | c.1000A>C p.T334P | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as COSV99783999; called by muse, mutect2
- HK2 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51877971; called by muse, mutect2, varscan2
- HSPG2 | c.2410A>G p.M804V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV65975052; called by muse, mutect2, varscan2
- HYDIN | c.6587C>G p.P2196R | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV59265487, COSV59275502; called by muse, mutect2, varscan2
- INA | c.1297A>C p.S433R | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV63976361; called by muse, mutect2, varscan2
- ITK | c.605A>C p.D202A | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV70064381; called by muse, mutect2
- JADE3 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99509419; called by muse, mutect2
- JAM3 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.142); catalogued as COSV54455406; called by muse, mutect2, varscan2
- KALRN | c.876del p.Q293Sfs*34 | Frame Shift Del (DEL) | VAF 13/106 reads (12%) | catalogued as COSV53760487; called by mutect2, pindel, varscan2
- KIF24 | c.3821G>A p.C1274Y | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV52660623; called by muse, mutect2, varscan2
- KLHL34 | c.1738A>C p.K580Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV65280029; called by muse, mutect2
- KLHL6 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58068437; called by muse, mutect2, varscan2
- KLK3 | c.234C>A p.H78Q | Missense Mutation (SNP) | VAF 125/206 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58102015; called by muse, mutect2, varscan2
- LIMS1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 61/472 reads (13%) | catalogued as COSV100185299, COSV57539833; called by muse, mutect2, varscan2
- LMNA | c.767T>G p.V256G | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as CM135989, COSV61543641; called by muse, mutect2, varscan2
- LMNTD1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 138/570 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV51449374, COSV99280000; called by muse, mutect2, varscan2
- LPAR4 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); catalogued as rs372050796, COSV70913115, COSV70913491; called by muse, mutect2, varscan2
- LRCH4 | c.1603C>A p.P535T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.086); catalogued as COSV59644054; called by muse, mutect2, varscan2
- LTBP1 | c.3730G>A p.D1244N (on ENST00000404816 / NM_206943.4; = p.D918N on NM_000627.4) | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55383190; called by muse, mutect2, varscan2
- LZTS1 | c.312dup p.K105Qfs*133 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs755712848; called by pindel, varscan2
- MANEA | c.173A>T p.N58I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62590268; called by muse, mutect2, varscan2
- MNDA | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV63741692; called by muse, mutect2, varscan2
- MTCL1 | c.2705C>A p.P902H (on ENST00000306329 / NM_001378206.1; = p.P542H on NM_015210.4) | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60409680; called by muse, mutect2, varscan2
- MTMR2 | c.373T>G p.L125V | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV100656470; called by muse, mutect2
- MUC17 | c.9295A>T p.T3099S | Missense Mutation (SNP) | VAF 138/452 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as COSV60297975; called by muse, mutect2, varscan2
- MYH4 | c.3721A>T p.T1241S | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99700059; called by muse, mutect2
- MYH7 | c.3102G>C p.L1034= | Splice Region (SNP) | VAF 10/214 reads (5%) | catalogued as COSV100805532; called by muse, mutect2
- NLRP12 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 91/378 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.152); catalogued as COSV60744103; called by muse, mutect2, varscan2
- NLRP13 | c.1212A>T p.E404D | Missense Mutation (SNP) | VAF 147/297 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as COSV61620193, COSV61623429; called by muse, mutect2, varscan2
- NNMT | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV55474561; called by muse, mutect2, varscan2
- NOMO1 | c.3656C>G p.T1219R | Missense Mutation (SNP) | VAF 34/1106 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.348); catalogued as COSV99814101; called by muse, mutect2
- NPAS2 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.03); catalogued as COSV59556413; called by muse, mutect2, varscan2
- NRAP | c.3659C>A p.P1220H (on ENST00000359988 / NM_001322945.2; = p.P1185H on NM_006175.4) | Missense Mutation (SNP) | VAF 424/739 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63492876; called by muse, mutect2, varscan2
- NUMBL | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248524795, COSV53284286, COSV99424748; called by muse, mutect2, varscan2
- NXN | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as rs1013992060, COSV61098965; called by muse, mutect2, varscan2
- OR4D6 | c.860A>C p.Y287S | Missense Mutation (SNP) | VAF 122/572 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55660574; called by muse, mutect2, varscan2
- OR4N2 | c.908A>T p.N303I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60053664; called by muse, mutect2, varscan2
- OR5H1 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 24/730 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as rs1328068502, COSV100641577; called by muse, mutect2
- OR7D2 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 175/784 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV60140746; called by muse, mutect2, varscan2
- OR8U1 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 271/630 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56414498; called by muse, varscan2
- PAX7 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64751771; called by muse, mutect2, varscan2
- PCDHB15 | c.1566G>C p.E522D | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51217442; called by muse, mutect2, varscan2
- PEX3 | c.530C>G p.T177R | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.185); catalogued as COSV62568598, COSV62569255; called by muse, mutect2, varscan2
- PIK3C2A | c.1200C>G p.H400Q | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56405408; called by muse, mutect2, varscan2
- PKHD1L1 | c.11698del p.L3900Ffs*38 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | catalogued as COSV101006731; called by mutect2, pindel, varscan2
- PLA2G6 | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as COSV59272332; called by muse, mutect2, varscan2
- PLXNC1 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs533262461, COSV51573002; called by muse, mutect2, varscan2
- PPBP | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV56020102; called by muse, mutect2, varscan2
- PPFIA4 | c.3094T>A p.W1032R (on ENST00000447715; = p.W1033R on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55319418; called by muse, mutect2, varscan2
- PPP1R17 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs777370118, COSV59612130; called by muse, mutect2, varscan2
- PRMT5 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 32/663 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756575000, COSV99362694; called by muse, mutect2
- PROS1 | c.1610T>G p.V537G | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV101260104; called by muse, varscan2
- PSD4 | c.1611C>G p.H537Q | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV55528798; called by muse, mutect2, varscan2
- PSMD3 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV52857920; called by muse, mutect2, varscan2
- PTGIS | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.245); catalogued as COSV54839366; called by muse, mutect2, varscan2
- PTPN13 | c.2018C>T p.T673I | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV57413571; called by muse, mutect2, varscan2
- PYHIN1 | c.1190A>T p.Q397L | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV63723529; called by muse, mutect2, varscan2
- RANBP6 | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52390801; called by muse, mutect2, varscan2
- RASGEF1C | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755415164, COSV63179542; called by muse, mutect2, varscan2
- RFT1 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as COSV99965281; called by muse, mutect2
- RGL4 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as COSV51944916; called by muse, mutect2, varscan2
- RIMS4 | c.666G>C p.E222D | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV65720382; called by muse, mutect2, varscan2
- RNF111 | c.2768A>T p.K923I (on ENST00000557998 / NM_001270530.1; = p.K915I on NM_017610.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62088659; called by muse, varscan2
- RNF112 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV71326997; called by muse, mutect2, varscan2
- RORB | c.434A>G p.N145S (on ENST00000396204 / NM_001365023.1; = p.N134S on NM_006914.4) | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as COSV65338638; called by muse, mutect2, varscan2
- RRAGD | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.674); catalogued as rs1165142740, COSV63269904; called by muse, mutect2, varscan2
- RYR1 | c.8843C>G p.S2948W | Missense Mutation (SNP) | VAF 97/486 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs759514075, COSV62105299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.8807C>G p.A2936G | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV63703400; called by muse, mutect2, varscan2
- S1PR3 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs764521861, COSV63980385, COSV63981148; called by muse, mutect2, varscan2
- SACS | c.4145A>G p.H1382R | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs550057119, COSV66544758; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCGB2A2 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs779171446, COSV57174834; called by muse, mutect2, varscan2
- SCLY | c.806A>T p.Y269F (on ENST00000651534; = p.Y261F on NM_016510.7) | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54543189; called by muse, mutect2, varscan2
- SCYL2 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV62570064; called by muse, mutect2, varscan2
- SH3TC2 | c.3134A>T p.E1045V | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV60466214; called by muse, mutect2, varscan2
- SHC1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.177); catalogued as COSV58316642; called by muse, mutect2, varscan2
- SIGLEC8 | c.1123C>A p.L375M | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58475111; called by muse, mutect2, varscan2
- SLC16A11 | c.1259G>T p.S420I (on ENST00000308009; = p.S396I on NM_153357.3) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs1037010388, COSV57274753; called by muse, mutect2, varscan2
- SLC2A5 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as rs748171858, COSV66237629; called by muse, mutect2
- SLC9C2 | c.1689G>C p.M563I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV62947882; called by mutect2, varscan2
- ST8SIA6 | c.800T>G p.L267R | Missense Mutation (SNP) | VAF 43/473 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66470587; called by muse, mutect2
- STAB2 | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 212/749 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66343962; called by muse, mutect2, varscan2
- STK38L | c.206A>C p.Q69P | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as COSV101198682; called by muse, mutect2
- STXBP5L | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99871347; called by muse, mutect2
- TAF6 | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); catalogued as COSV59842877; called by muse, mutect2, varscan2
- TDG | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378394461, COSV57167852; called by muse, mutect2, varscan2
- TENM4 | c.5324G>A p.G1775D | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53654333; called by muse, mutect2
- TIAM1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54565684; called by muse, mutect2, varscan2
- TNF | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV69305182; called by muse, mutect2, varscan2
- TRIP4 | c.618+1G>T p.X206_splice | Splice Site (SNP) | VAF 29/82 reads (35%) | catalogued as COSV56032331; called by muse, mutect2, varscan2
- UGGT1 | c.1246A>G p.N416D | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.034); catalogued as COSV52139564; called by muse, mutect2, varscan2
- UMOD | c.1667C>G p.A556G | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV56778119; called by muse, mutect2, varscan2
- UNC13A | c.5042C>T p.A1681V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99406710, COSV99407246; called by muse, mutect2, varscan2
- USH2A | c.8036A>G p.H2679R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); catalogued as COSV100227282; called by muse, varscan2
- UST | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV66549197; called by muse, mutect2, varscan2
- WBP2NL | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 278/619 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV60920451; called by muse, mutect2, varscan2
- WDTC1 | c.1990G>A p.D664N (on ENST00000319394 / NM_001276252.2; = p.D663N on NM_015023.5) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs138646253; called by muse, mutect2, varscan2
- XKR3 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as COSV58887397; called by muse, mutect2, varscan2
- XPO6 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV58969512; called by muse, mutect2, varscan2
- ZFP37 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1414705430, COSV65288055; called by muse, mutect2, varscan2
- ZNF583 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 75/355 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV52400968, COSV52404032; called by muse, mutect2, varscan2
- ZNF862 | c.3394A>G p.K1132E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV99783083; called by muse, mutect2, varscan2
- ZNF91 | c.2825A>C p.E942A | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs762775014, COSV56089627; called by muse, mutect2, varscan2
- ZSCAN20 | c.1789A>G p.T597A | Missense Mutation (SNP) | VAF 170/414 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755926539, COSV63683928; called by muse, varscan2
- ZXDC | c.991T>C p.S331P | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs1244248729, COSV60447989; called by muse, mutect2, varscan2
- ADRB2 | c.1053del p.N352Mfs*91 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | called by mutect2, varscan2
- ASPM | c.2254_2272del p.S752Lfs*5 | Frame Shift Del (DEL) | VAF 20/173 reads (12%) | called by mutect2, pindel
- EID3 | c.779_804del p.F260Wfs*8 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- GRIN2C | c.399_399+12del p.X133_splice | Splice Site (DEL) | VAF 6/64 reads (9%) | called by mutect2, varscan2
- HPGDS | c.161del p.L54Wfs*12 | Frame Shift Del (DEL) | VAF 53/93 reads (57%) | called by mutect2, pindel, varscan2
- NFATC2 | c.1681_1682del p.Q561Dfs*4 | Frame Shift Del (DEL) | VAF 21/178 reads (12%) | called by pindel*, varscan2
- POMGNT1 | c.795_797del p.R267del | In Frame Del (DEL) | VAF 12/60 reads (20%) | called by pindel, varscan2
- SARS2 | c.195_218del p.C66_A73del | In Frame Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.3144G>A p.A1048= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as rs754047149, COSV50774614, COSV99176695; called by muse, mutect2, varscan2
- AHNAK | c.17511G>A p.E5837= | Silent (SNP) | VAF 23/662 reads (3%) | catalogued as COSV99945072; called by muse, mutect2
- BCOR | c.4101C>T p.H1367= (on ENST00000378444 / NM_001123385.2; = p.H1333= on NM_017745.6) | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV60706365; called by muse, mutect2, varscan2
- BMP3 | c.450A>G p.G150= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV51091576; called by muse, mutect2, varscan2
- BRINP2 | c.432T>A p.T144= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV100837776; called by muse, mutect2
- BRSK1 | c.582C>A p.P194= | Silent (SNP) | VAF 33/263 reads (13%) | catalogued as COSV58668724; called by muse, mutect2, varscan2
- CBLL1 | c.90C>T p.L30= | Silent (SNP) | VAF 65/268 reads (24%) | catalogued as COSV56029998; called by muse, mutect2, varscan2
- CCDC88C | c.3225G>C p.L1075= | Silent (SNP) | VAF 28/33 reads (85%) | catalogued as COSV66240276; called by muse, mutect2, varscan2
- CEP290 | c.5916T>C p.D1972= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as COSV58354340; called by muse, mutect2, varscan2
- EFCAB12 | c.72C>T p.P24= | Silent (SNP) | VAF 71/127 reads (56%) | catalogued as COSV58177959; called by muse, mutect2, varscan2
- EIF4G1 | c.2679G>T p.R893= (on ENST00000346169 / NM_198241.3; = p.R698= on NM_004953.5) | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV59992734; called by muse, mutect2, varscan2
- EVA1C | c.1032A>G p.R344= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as COSV55825881; called by muse, mutect2, varscan2
- FAT1 | c.7062G>A p.R2354= | Silent (SNP) | VAF 123/153 reads (80%) | catalogued as rs756397442, COSV71674973; called by muse, mutect2, varscan2
- GABBR1 | c.1383A>T p.T461= | Silent (SNP) | VAF 18/327 reads (6%) | catalogued as COSV100589352; called by muse, mutect2
- GABRG2 | c.495C>A p.T165= | Silent (SNP) | VAF 86/203 reads (42%) | catalogued as COSV62720788; called by muse, mutect2, varscan2
- GLDN | c.669C>T p.S223= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV59091610; called by muse, mutect2, varscan2
- HELQ | c.3138C>G p.L1046= | Silent (SNP) | VAF 67/296 reads (23%) | catalogued as rs768787457, COSV55026412, COSV55026723; called by muse, mutect2, varscan2
- KCNH1 | c.2199G>A p.P733= (on ENST00000271751 / NM_172362.3; = p.P706= on NM_002238.4) | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as rs756120939, COSV55079432; called by muse, mutect2, varscan2
- LIMS1 | c.60T>C p.A20= | Silent (SNP) | VAF 60/463 reads (13%) | catalogued as COSV100185296; called by muse, mutect2, varscan2
- LRRC39 | c.825C>T p.F275= | Silent (SNP) | VAF 89/179 reads (50%) | catalogued as COSV61583636; called by muse, mutect2, varscan2
- MYH14 | c.5394C>G p.A1798= | Silent (SNP) | VAF 47/228 reads (21%) | catalogued as COSV51827129; called by muse, mutect2, varscan2
- MYH7 | c.4761G>A p.K1587= | Silent (SNP) | VAF 19/407 reads (5%) | catalogued as COSV100805531; called by muse, mutect2
- N4BP2L2 | c.2118A>C p.I706= (on ENST00000674422; = p.I277= on NM_033111.4) | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100678636; called by muse, mutect2
- OBSCN | c.13035G>A p.G4345= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1372858045, COSV52758449, COSV99470598, COSV99484442; called by muse, mutect2, varscan2
- OR10R2 | c.714T>C p.Y238= | Silent (SNP) | VAF 15/365 reads (4%) | catalogued as COSV100936740; called by muse, mutect2
- OR13H1 | c.441C>A p.T147= | Silent (SNP) | VAF 29/828 reads (4%) | catalogued as COSV100088080; called by muse, mutect2
- OR5AS1 | c.837T>G p.T279= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV57982705; called by muse, mutect2, varscan2
- PAX4 | c.693C>G p.L231= | Silent (SNP) | VAF 55/266 reads (21%) | catalogued as COSV58390288; called by muse, mutect2, varscan2
- PCDH1 | c.2520G>C p.G840= | Silent (SNP) | VAF 164/400 reads (41%) | catalogued as COSV54617684; called by muse, mutect2, varscan2
- PCDHB7 | c.1737G>A p.A579= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs567529552, COSV50797976; called by muse, mutect2, varscan2
- PIAS1 | c.477C>T p.D159= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs1308624111, COSV51035736; called by muse, mutect2, varscan2
- PRAMEF1 | c.892T>C p.L298= | Silent (SNP) | VAF 31/817 reads (4%) | catalogued as COSV100179309, COSV60010135; called by muse, mutect2
- PTPRN | c.1731G>C p.V577= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV55350706; called by muse, mutect2, varscan2
- RIMS4 | c.667C>T p.L223= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as rs764339672, COSV65720380; called by muse, mutect2, varscan2
- SERPINA12 | c.438A>G p.P146= | Silent (SNP) | VAF 22/384 reads (6%) | catalogued as COSV100369529; called by muse, mutect2
- SHARPIN | c.1086C>T p.A362= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV59644822; called by muse, mutect2, varscan2
- SPTA1 | c.6975T>G p.A2325= | Silent (SNP) | VAF 146/374 reads (39%) | catalogued as COSV63757293; called by muse, mutect2, varscan2
- TEX47 | c.342T>C p.Y114= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV51879610, COSV51879791, COSV99787243; called by muse, mutect2, varscan2
- TTN | c.50844C>A p.G16948= (on ENST00000591111; = p.G9524= on NM_003319.4) | Silent (SNP) | VAF 26/185 reads (14%) | catalogued as COSV60237556; called by muse, mutect2, varscan2
- WNT2 | c.768T>A p.A256= | Silent (SNP) | VAF 117/517 reads (23%) | catalogued as COSV55412731; called by muse, mutect2, varscan2
- ZNF324B | c.894G>C p.S298= | Silent (SNP) | VAF 83/199 reads (42%) | catalogued as COSV100351838, COSV60742768; called by muse, mutect2, varscan2
- ZNF333 | c.1077C>A p.I359= | Silent (SNP) | VAF 37/552 reads (7%) | catalogued as COSV99468650; called by muse, mutect2
- ZNF613 | c.1753T>C p.L585= (on ENST00000293471 / NM_001031721.4; = p.L549= on NM_024840.4) | Silent (SNP) | VAF 37/181 reads (20%) | catalogued as rs1000726756, COSV53273195; called by muse, mutect2, varscan2
- MIR518A2 | n.23G>T | RNA (SNP) | VAF 127/607 reads (21%) | called by muse, mutect2, varscan2
- ODF2 | c.1911+21G>T | Intron (SNP) | VAF 28/104 reads (27%) | catalogued as COSV63548329; called by muse, mutect2, varscan2
- OR2U1P | n.388T>A | RNA (SNP) | VAF 13/397 reads (3%) | called by muse, mutect2
